Somatic mutation profile of tumor specimen MP2PRT-PAUYFM-TBP1-A (aliquot MP2PRT-PAUYFM-TBP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUYFM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,208 days).
Specimen MP2PRT-PAUYFM-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54d0d8c6-b8f6-4c4d-b48d-511897a0332c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYFM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYFM-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9d384e1-bf35-4800-b584-cfce8253c2fd

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2524T>C p.Y842H | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519762, COSV54057460; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 116/503 reads (23%) | catalogued as rs963577631; called by muse, mutect2, varscan2
- CAPN5 | c.907C>T p.R303C (on ENST00000456580; = p.R263C on NM_004055.5) | Missense Mutation (SNP) | VAF 190/403 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs373951153; called by muse, varscan2
- FLT3 | c.1775T>A p.V592D | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54051432, COSV54058572, COSV54074139; called by muse, mutect2, varscan2
- MALRD1 | c.3512C>T p.T1171M | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs751313037; called by muse, mutect2, varscan2
- CPA4 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- HOXB13 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- IKZF1 | c.449_450insGGGGCGCC p.C150Wfs*46 | Frame Shift Ins (INS) | VAF 98/262 reads (37%) | called by mutect2, pindel, varscan2
- SLC15A3 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 274/524 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBC | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, varscan2
- ABCA13 | c.6333G>A p.P2111= | Silent (SNP) | VAF 103/222 reads (46%) | catalogued as rs368987851; called by muse, mutect2, varscan2
- CADM2 | c.687T>G p.V229= (on ENST00000407528 / NM_001167674.2; = p.V231= on NM_153184.4) | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as COSV67355364; called by muse, mutect2, varscan2
- CHD5 | c.4635G>A p.S1545= | Silent (SNP) | VAF 208/445 reads (47%) | catalogued as rs140639533; called by muse, mutect2, varscan2
- NOS1AP | c.787C>T p.L263= | Silent (SNP) | VAF 133/264 reads (50%) | catalogued as COSV100723507; called by muse, mutect2, varscan2
- TGM6 | c.1386C>T p.F462= | Silent (SNP) | VAF 115/213 reads (54%) | catalogued as rs1263759704, COSV52479748; called by muse, mutect2, varscan2
